Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A28K, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A28K-01A (Primary Tumor).

Path (First Tumor)

Tumor Site:	Hepatic Flexure Proximal		
Date of Cancer Sample Procurement:			
Histology:	Adenocarcinoma		
Description of other histology:			
Grade:	Well Differentiated		
Mucinous:	☐ No	☒ Yes	☐ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No	☐ Yes	☐ Unknown
Host Response:			
Crohn's like reaction	☐ None	☒ Yes	☐ Unknown
Plasma cell rich stroma	☐ No	☐ Yes	☐ Unknown
Growth Pattern:	☒ Expansile	☐ Invasive	☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☐ No	☐ Yes	☒ Unknown
Angiolymphatic Invasion:	☒ No	☐ Yes	☐ Unknown
Mutator Phenotype:	☐ No	☒ Yes	☐ Unknown
Number of Slides	1		
Garland Necrosis present:	☒ No	☐ Yes	☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	0		
Pathologist Comment:			

ICD-0-3

Path
CQCF

adenocarcinoma, mucinous, NOS 8480/3

site: hepatic flexure c18.3 w 5/3/11

Primary Malignancy History		
Distal Synchronous Primary Listed		
Case is (cin,le):		

Source: NCI Genomic Data Commons file 4d1c73fb-5901-49f7-a6aa-e8a7956339c3 (TCGA-DM-A28K.499EEF9A-F77A-4F0D-A575-CB52AAB54E9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).